Surgical pathology report (de-identified scan), TCGA case TCGA-76-6663, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6663-01A (Primary Tumor).

[page 1 of 3]
ADDED

TCGA-76-6663

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right frontal brain tumor: GLIOBLASTOMA, WHO GRADE IV.
2. Right frontal brain tumor: GLIOBLASTOMA, WHO GRADE IV. SEE MICROSCOPIC DESCRIPTION.

This diagnostic report has been personally interpreted by the signatory of record.

Aperio

Ki67

Percent : 15%

Cells counted : 27,480 cells

This test was performed by IHC in conjunction with the Aperio-computer assisted image analysis.

Addendum

IMMUNOHISTOCHEMICAL STAINS

GFAP: POSITIVE STAINING OF TUMOR CELLS.

P53: POSITIVE STAINING OF SCATTERED TUMOR CELL NUCLEI.

[page 2 of 3]
2. Right frontal brain tumor:

Specimen Type/Procedure: Resection

Frozen tissue

Unfrozen for routine permanent paraffin sections

Tumor Site: Brain/cerebrum-Frontal

Histologic Type and Grade: Glioblastoma (WHO grade IV)

Histologic Grade: WHO Grade IV

Margins: Cannot be assessed

Ancillary Studies: Immunohistochemistry: Ki67, p53, GFAP

The tumor is composed of pleomorphic neoplastic astrocytes. Mitotic figures are identified on tumor cells. Tumor necrosis and endothelial proliferation are identified. Case reviewed in conference with Dr.

██████████ An addendum with the results of immunohistochemical stains will be issued.

1. Right frontal brain tumor: Glioblastoma. Frozen section diagnosis by [REDACTED]

right frontal brain tumor

1: Right frontal brain tumor

2: Right frontal brain tumor

Gross Description:

1. **Right frontal brain tumor:** Received fresh for frozen section in a specimen container labeled patient's name and "#1 right frontal brain tumor", is a 1 x 0.9 x 0.3 cm fragment tan-pink soft tissue. Touch preparations are made and approximately 50% of the specimen is submitted for frozen section analysis. Remainder of the specimen is entirely submitted for a total of 2 cassettes.

[page 3 of 3]
[REDACTED]

B. remainder of specimen

2. Right frontal brain tumor: Received in formalin, in a specimen container labeled with the patient's name and "#2 right frontal brain tumor", is a 6.0 x 5.5 x 2.4 cm aggregate of tan-pink soft tissue. The specimen is entirely submitted in 5 cassettes.

Histology Laboratory
H&E

Part 2: Right frontal brain tumor
GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)
KI 67 (Aperio)
P 53

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Pathway Her-2/neu (4B5) (Rabbit monoclonal) - Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

Interpretation follows the manufacturer's recommendation.

3. EGFR (3C6) (Mouse Monoclonal) Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

4. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Source: NCI Genomic Data Commons file 05747a87-78ea-4f1b-aa95-5a1dc68f2977 (TCGA-76-6663.E6733441-1472-4DEB-9654-8F5059B0B72C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).